Somatic mutation profile of tumor specimen TCGA-QH-A6CS-01A (aliquot TCGA-QH-A6CS-01A-11D-A31L-08) from TCGA case TCGA-QH-A6CS, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 41.3 years (15,092 days).
Specimen TCGA-QH-A6CS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b260667-d765-4e0c-9e28-ba6537d749c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QH-A6CS-10A (Blood Derived Normal), aliquot TCGA-QH-A6CS-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/252d8e71-5b0c-45de-9c02-82c019e7d6cc

The open-access MAF lists 22 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 15, Silent 5, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.2065C>T p.R689W (on ENST00000281708 / NM_001349798.2; = p.R609W on NM_018315.5) | Missense Mutation (SNP) | VAF 23/156 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55895191, COSV55934968; called by muse, mutect2, varscan2
- PTEN | c.955dup p.T319Nfs*6 | Frame Shift Ins (INS) | VAF 21/90 reads (23%) | catalogued as rs786204892, CI075686, COSV64290023; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- APBB2 | c.2131G>T p.V711L (on ENST00000295974 / NM_001166050.2; = p.V712L on NM_004307.2) | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as rs759827967, COSV99922565; called by muse, mutect2, varscan2
- BCAS4 | c.275T>A p.I92N | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99372302; called by muse, mutect2, varscan2
- CNTRL | c.1342G>A p.A448T | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs983093653, COSV99441321; called by muse, mutect2
- DHFR | c.236A>G p.E79G | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV101459014; called by muse, mutect2
- EIF2AK1 | c.177C>A p.F59L | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV99551616; called by muse, mutect2, varscan2
- F8 | c.5999G>A p.G2000D | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM003815, CM100253, CM103956, CS063308, COSV100811302; called by muse, mutect2, varscan2
- HERC2 | c.4382G>A p.G1461D | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.102); catalogued as COSV99871475; called by muse, mutect2, varscan2
- KCNIP1 | c.497A>G p.Y166C (on ENST00000411494 / NM_001034837.3; = p.Y155C on NM_014592.4) | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61081951; called by muse, mutect2, varscan2
- LAMA2 | c.7150G>T p.D2384Y | Missense Mutation (SNP) | VAF 15/161 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV101370211; called by muse, mutect2
- SHANK1 | c.2444A>G p.Y815C | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99520412; called by muse, mutect2
- SPATA4 | c.519G>T p.Q173H | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99708833; called by muse, mutect2, varscan2
- UTP23 | c.653A>G p.Q218R | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV100561116; called by muse, mutect2, varscan2
- ZFP64 | c.761C>T p.T254M | Missense Mutation (SNP) | VAF 34/195 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53799372, COSV99402039; called by muse, mutect2, varscan2
- NF1 | c.4974del p.L1659Sfs*39 (on ENST00000358273 / NM_001042492.3; = p.L1638Sfs*39 on NM_000267.3) | Frame Shift Del (DEL) | VAF 18/111 reads (16%) | called by mutect2, pindel, varscan2
- PCDHB9 | c.570A>G p.I190M | Missense Mutation (SNP) | VAF 43/256 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- AZGP1 | c.606C>T p.D202= | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as COSV99447711; called by muse, mutect2, varscan2
- GALR2 | c.279C>T p.F93= | Silent (SNP) | VAF 11/129 reads (9%) | catalogued as COSV100203446; called by muse, mutect2
- PCDHA7 | c.1353C>T p.N451= | Silent (SNP) | VAF 27/187 reads (14%) | catalogued as rs781957990, COSV65343883; called by muse, mutect2, varscan2
- PLPPR5 | c.900A>G p.V300= | Silent (SNP) | VAF 6/97 reads (6%) | catalogued as rs1461859164, COSV99587040; called by muse, mutect2
- WASHC3 | c.336A>G p.T112= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as rs748691290, COSV99527399; called by muse, mutect2, varscan2
